Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3852, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3852-01A (Primary Tumor).

Findings and diagnosis relating to the problem:

This is an invasive, mucinous adenocarcinoma of the colon, G3, with penetration of all parietal layers (pT3) and vascular infiltrates (L1, V1) with free resection margins in the mucosa region with a regular mucosa, submucosa and muscularis, as well as mature connective tissue in the deep resection margin area and free lymph nodes, in addition there are tubulovillous adenomas with focally severe dysplasia (high-risk intraepithelial neoplasia) and omental tissue with reactive lesions.

Tumor classification:

ICDO-DA-M 8140/3

G3

pT3, L1, V1, pN0 (0 of 13).

Source: NCI Genomic Data Commons file 36cb415b-ac48-49e2-aec5-46807433f04e (TCGA-AA-3852.27E4A994-74C4-47AB-8F7C-00F2C468F3EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).